Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MU-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:

Male

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

In transit met (R) shoulder - WEG. & FNA positive LN (R) axilla - axillary dissection. Right axillary clearance - marking stitch - APEX. tumour bank.

MACROSCOPIC DESCRIPTION

(Dr.

Two specimens received.

* 1. "WIDE EXCISION MELANOMA IN TRANSIT RIGHT SHOULDER". An ellipse of skin, 86 x 50 x depth of 23mm, bearing a centrally located red/brown nodular lesion 45 x 40mm. Skin surface is E-squared defect 18 x 13mm from assumed tumour banking. There is a suture on one long margin will be designated 12 o'clock. Serial sectioning reveals multiple pale tan to dark brown nodules to a depth of 22mm. Some small areas of necrosis noted within the mass. One representative section through mid specimen showing closest deep surgical margin embedded in Blocks A-C.

2. "RIGHT AXILLARY CLEARANCE". A piece of fibrofatty tissue, 140 x 120 x 40mm weighing 250g. There is a suture at one end indicating apex end, at this end is attached skeletal muscle 90 x 55 x 15mm. Multiple enlarged lymph nodes noted, the largest is 30 x 20 x 20mm. Located at the apex end of the specimen. 15 lymph nodes identified. Embedded in Blocks A-H.

- A. Representative slice through largest node.
- B. One node bisected.
- C. Four nodes.
- D. One node.
- E. Two nodes.
- F. One node. Representative section.
- G. Four nodes.
- H. One node.

ICD-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous, shoulder
lw 8/24/11 c49.1

MICROSCOPIC REPORT

1. "WIDE EXCISION MELANOMA IN TRANSIT RIGHT SHOULDER".

The sections show skin and underlying subcutis. Centered within the subcutis is a circumscribed tumour nodule composed of large epithelioid, some of which include intracytoplasmic pigment, consistent with metastatic melanoma. There are large central areas of necrosis. The tumour is about 1mm clear of the deep margin and 9mm clear of the nearest peripheral margin. There is a peritumoral infiltrate of lymphocytes in some areas and the overlying epidermis and dermis show some inflammatory changes.

2. "RIGHT AXILLARY CLEARANCE".

The sections show metastatic melanoma in one of sixteen lymph nodes. The involved lymph node (that measured 30mm in maximum dimension macroscopically) is extensively replaced by a pleomorphic

[page 2 of 2]
Requested by:

MRN/Name:
Location:
Accession:

HISTOPATHOLOGY REPORT

epithelioid cell tumour consistent with metastatic melanoma. There is focal necrosis. Probably extra nodal spread is present that is difficult to measure but is probably approximately 7 x 3mm.

SUMMARY

1. SKIN OF RIGHT SKIN / SUBCUTIS FROM RIGHT SHOULDER.

- metastatic melanoma. Please see report.

/

2. RIGHT AXILLARY LYMPH NODES.

- metastatic melanoma in one of sixteen lymph nodes. Please see report.

REPORTED BY: Prof. J

Source: NCI Genomic Data Commons file 45a1ec7d-766d-4508-b6ee-63dc9672649d (TCGA-EE-A2MU.E6F4543C-6487-4B2B-9BFB-E59002823BF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).